Somatic mutation profile of tumor specimen MP2PRT-PANVDK-TMP1-A (aliquot MP2PRT-PANVDK-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANVDK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (534 days).
Specimen MP2PRT-PANVDK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 185fdb5f-5d0b-49b1-8496-83f1c5a6fd90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANVDK-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANVDK-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77b173d1-80ca-429a-8e8c-eccf2d0bc4e1

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 203/550 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- H1-10 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 44/757 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61549728; called by muse, mutect2
- RBMXL3 | c.2320G>A p.G774R | Missense Mutation (SNP) | VAF 365/940 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as rs1026886721, COSV100407347; called by muse, mutect2, varscan2
- WDR49 | c.2011C>T p.P671S (on ENST00000308378 / NM_001366158.1; = p.P1012S on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 133/323 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52987378; called by muse, mutect2, varscan2
- ANXA1 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 30/414 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); called by muse, mutect2
- NLRP14 | c.3234T>A p.D1078E | Missense Mutation (SNP) | VAF 176/402 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OSCP1 | c.474T>C p.G158= (on ENST00000356637 / NM_001330493.1; = p.G148= on NM_145047.5) | Silent (SNP) | VAF 123/305 reads (40%) | catalogued as rs1363458292; called by muse, mutect2, varscan2
